Somatic mutation profile of tumor specimen MP2PRT-PAUKDI-TMP1-A (aliquot MP2PRT-PAUKDI-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUKDI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (664 days).
Specimen MP2PRT-PAUKDI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66aa48bb-8f77-45a2-b029-cd7fee2504cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKDI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKDI-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ab551b5-a8b0-4f22-8b44-5e1ba3da51c2

The open-access MAF lists 14 somatic variants for this specimen: 6 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 4, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 125/283 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 111/482 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs545327036; called by muse, mutect2, varscan2
- TECTA | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.517); catalogued as rs143120527; called by muse, mutect2, varscan2
- BTBD7 | c.969dup p.Y324Ifs*22 | Frame Shift Ins (INS) | VAF 102/414 reads (25%) | called by mutect2, varscan2
- CATSPERE | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDB1 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 91/205 reads (44%) | called by muse, mutect2, varscan2
- BAHCC1 | c.5625G>A p.S1875= | Silent (SNP) | VAF 141/523 reads (27%) | catalogued as rs371234536; called by muse, mutect2, varscan2
- CASC3 | c.849C>T p.R283= | Silent (SNP) | VAF 122/400 reads (31%) | called by muse, mutect2, varscan2
- FAM189A1 | c.1197C>T p.S399= | Silent (SNP) | VAF 114/284 reads (40%) | catalogued as rs747740039, COSV54267828; called by muse, mutect2, varscan2
- MEIS1 | c.489C>T p.H163= | Silent (SNP) | VAF 84/189 reads (44%) | catalogued as rs540467903; called by muse, mutect2, varscan2
- MOBP | c.480G>A p.P160= (on ENST00000420739; = p.P184= on NM_001278322.2) | Silent (SNP) | VAF 20/552 reads (4%) | called by muse, mutect2
- TUBB | c.1056C>T p.A352= | Silent (SNP) | VAF 222/848 reads (26%) | catalogued as rs773052081; called by muse, mutect2, varscan2
- ZNF496 | c.1020G>A p.P340= | Silent (SNP) | VAF 80/197 reads (41%) | catalogued as rs368972635, COSV99666220; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2006+1377C>T | Intron (SNP) | VAF 106/228 reads (46%) | catalogued as rs777489090; called by muse, mutect2, varscan2
